Gene-level copy-number profile of tumor specimen TCGA-AA-3488-01A from TCGA case TCGA-AA-3488, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IV; Age at diagnosis: 58.9 years (21,519 days).
Specimen TCGA-AA-3488-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.05516ff4-2bbe-455b-93f4-928344626002.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3488-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/45e32be8-53ab-448e-a513-f4f0019793c1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 1,176; copy number 2: 19,783; copy number 3: 24,099; copy number 4: 10,803; copy number 5: 1,764; copy number 6: 1,662; copy number 7: 465; copy number 8: 65.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AA-3488-01): tumor purity 0.82, ploidy 3.03, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:6,873,899–7,004,112, 2 genes: RNU6-457P, RNU6-328P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 530 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:119,730,774–145,066,685, 465 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr13:51,082,119–53,939,960, 65 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,176. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
